Gene-level copy-number profile of tumor specimen TCGA-3C-AAAU-01A from TCGA case TCGA-3C-AAAU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 55.3 years (20,211 days).
Specimen TCGA-3C-AAAU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.d247c6c5-a429-41ae-83d9-bf8307ab76e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3C-AAAU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75cfa36d-325f-4fd3-a908-ef17980ed614

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,964; copy number 2: 23,506; copy number 3: 31,252; copy number 4: 1,543; copy number 5: 629; copy number 6: 190; copy number 7: 221; copy number 8: 109; copy number 9: 23; copy number 10: 68; copy number 11: 150; copy number 12: 17; copy number 13: 5; copy number 14: 3; copy number 15: 2; copy number 17: 25; copy number 19: 73; copy number 26: 7; copy number 27: 2; copy number 29: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3C-AAAU-01A-11D-A41E-01): tumor purity 0.81, ploidy 2.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 731 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,923,317–151,195,321, 66 genes, copy number 11–19 (broad region; genes not listed).
- chr4:72,807,267–74,918,138, 44 genes, copy number 8–29: HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, AC098825.1, HSPE1P23.
- chr4:76,401,251–77,150,437, 18 genes, copy number 11–26: AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P.
- chr4:77,216,416–77,216,878, 1 gene, copy number 7: AC008638.3.
- chr4:77,958,000–80,204,329, 33 genes, copy number 8–12: AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4, ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3, PAQR3, RN7SL127P, LINC01088, NAA11, GK2, LINC00989, OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75, ANTXR2, KPNA2P1, RPSAP39, AC021127.1, PRDM8.
- chr11:59,978,020–61,251,444, 46 genes, copy number 8 (within-gene range 3–8): OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7, MS4A14, MS4A5, MS4A1, MS4A12, MS4A13, MS4A19P, LINC00301, MS4A8, MS4A18, MS4A15, MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5.
- chr11:66,312,853–68,053,762, 115 genes, copy number 7 (broad region; genes not listed).
- chr11:69,425,690–70,398,488, 31 genes, copy number 8 (within-gene range 6–8): AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:77,034,398–77,918,432, 22 genes, copy number 9 (within-gene range 6–9): B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1.
- chr11:77,914,990–77,915,275, 1 gene, copy number 9: AP002812.4.
- chr11:78,324,758–78,444,049, 4 genes, copy number 10–15 (within-gene range 2–15): AP003086.1, AP003086.3, AP003086.2, LINC02728.
- chr12:63,623,788–63,795,718, 1 gene, copy number 11 (within-gene range 4–11): AC084357.2.
- chr12:63,682,523–67,970,017, 97 genes, copy number 11–17 (within-gene range 1–17) (broad region; genes not listed).
- chr12:68,201,349–71,118,247, 67 genes, copy number 11–19 (broad region; genes not listed).
- chr12:71,839,707–72,728,844, 9 genes, copy number 11: TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr20:52,972,358–53,495,330, 1 gene, copy number 7 (within-gene range 6–7): TSHZ2.
- chr20:53,137,293–54,269,542, 22 genes, copy number 7: AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1.
- chr20:60,083,360–64,313,132, 153 genes, copy number 7–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,964. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
